Gene-level copy-number profile of tumor specimen TCGA-N9-A4Q3-01A from TCGA case TCGA-N9-A4Q3, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IA; Age at diagnosis: 65.8 years (24,031 days).
Specimen TCGA-N9-A4Q3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.32aead92-ec91-4f63-a65a-b48d9e9d906d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N9-A4Q3-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/488ab084-20f4-4c8d-bdeb-91bb9deb67ca

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 693; copy number 2: 13,981; copy number 3: 25,265; copy number 4: 11,824; copy number 5: 5,315; copy number 6: 460; copy number 7: 916; copy number 8: 416; copy number 9: 170; copy number 10: 23; copy number 11: 589; copy number 12: 13; copy number 13: 58; copy number 14: 50; copy number 15: 15; copy number 16: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N9-A4Q3-01A-11D-A28Q-01): tumor purity 0.89, ploidy 3.29, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,276 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–2,331,664, 41 genes, copy number 7: FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1, LINC01874, AC093326.2, LINC01875, AC093326.1, TMEM18, TMEM18-DT, AC092159.3, AC092159.2, AC092159.1, AC116609.3, AC116609.2, AC116609.1, LINC01115, LINC01939, AC113607.1, SNTG2-AS1, SNTG2, AC114808.1, AC114808.2, AC108462.1, AC105450.1, TPO, AC141930.1, AC141930.2, AC144450.1, PXDN, MYT1L, AC093390.2, AC093390.1, MYT1L-AS1.
- chr2:4,514,204–7,141,544, 30 genes, copy number 8: NPM1P48, LINC01249, AC092169.1, RNU6-649P, AC073143.1, AC107057.1, LINC01248, AC108025.1, SOX11, AC010729.2, AC010729.1, LINC01810, SILC1, MIR7158, AC017053.1, LINC01247, LINC01824, PIK3CDP1, MIR7515HG, AC097517.1, MIR7515, LINC00487, NRIR, CMPK2, RSAD2, AC017076.1, GRASLND, RNF144A, AC068481.1, RN7SKP112.
- chr2:15,166,914–18,361,616, 41 genes, copy number 7 (within-gene range 6–7): NBAS, RPS26P18, AC008278.2, DDX1, AC008278.1, LINC01804, AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3, AC010745.5, AC010745.4, AC010880.1, AC104623.1, AC104623.2, CYRIA, AC008164.1, AC008069.1, LINC01866, RN7SKP168, ZFYVE9P2, PSMC1P10, RAD51AP2, VSNL1, SMC6, GEN1, MSGN1, KCNS3, AC079802.1.
- chr2:45,388,680–46,266,971, 9 genes, copy number 7: SRBD1, RN7SL414P, PRKCE, PRKCE-AS1, RPL26P15, AC017006.2, AC017006.1, RPL36AP14, Metazoa_SRP.
- chr2:48,809,340–49,419,013, 1 gene, copy number 7 (within-gene range 5–7): AC009975.1.
- chr2:48,962,157–49,888,986, 7 genes, copy number 7 (within-gene range 5–7): FSHR, MIR548BA, AC009975.2, RNU6-439P, AC009971.1, RPL7P13, SNORA75.
- chr2:91,736,726–98,936,259, 168 genes, copy number 7 (broad region; genes not listed).
- chr3:105,366,909–111,275,563, 75 genes, copy number 7 (broad region; genes not listed).
- chr4:90,838,903–90,839,037, 1 gene, copy number 7: TMSB4XP8.
- chr4:91,603,275–91,605,292, 1 gene, copy number 8: AC110774.1.
- chr10:53,802,771–61,026,420, 53 genes, copy number 8–14 (within-gene range 3–14): PCDH15, RNU6-687P, AL353784.1, NEFMP1, MIR548F1, AC051618.1, AC016822.1, AL355314.1, AL355314.2, MTRNR2L5, GAPDHP21, AC069545.1, ZWINT, AC010996.1, AC025039.1, MIR3924, AL731534.1, AC006484.1, MRPS35P3, AC026884.1, IPMK, TPT1P10, CISD1, AC016396.1, AC016396.2, UBE2D1, TFAM, BICC1, FAM133CP, RN7SKP196, LINC00844, RPLP1P10, TRAF6P1, PHYHIPL, FAM13C, AC025038.1, AL355474.1, MRPL50P4, AC026391.1, SLC16A9, MRLN, CCDC6, LINC01553, ANK3, AL592430.1, Y_RNA, AL592430.2, ARL4AP1, ANK3-DT, CDK1, RHOBTB1, RNU2-72P, LINC00845.
- chr12:66,767–44,503,596, 941 genes, copy number 7–12 (broad region; genes not listed).
- chr12:64,696,191–69,601,570, 112 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr13:67,831,876–68,331,613, 7 genes, copy number 7: NPM1P22, OR7E111P, OR7E33P, AL590027.1, ELL2P3, HNRNPA1P18, RPL37P21.
- chr13:75,109,587–77,645,263, 38 genes, copy number 10–15 (within-gene range 4–15): RNU6-38P, SSR1P2, CTAGE11P, LINC01078, TBC1D4, AL139230.1, COMMD6, UCHL3, AL137782.1, LMO7-AS1, LMO7, AL137244.1, FAM204CP, LMO7DN, LMO7DN-IT1, LINC00561, LINC01034, RN7SL571P, AL136441.1, AL161717.1, AL365394.1, KCTD12, AC000403.1, BTF3P11, ACOD1, RPL7P44, DHX9P1, CLN5, AC001226.2, FBXL3, MYCBP2-AS1, AC001226.1, MYCBP2, MYCBP2-AS2, AL159158.1, SCEL, AL137140.1, SCEL-AS1.
- chr13:98,683,801–98,752,672, 1 gene, copy number 8: SLC15A1.
- chr13:98,832,084–98,872,005, 2 genes, copy number 8: DOCK9-AS1, AL161420.1.
- chr19:9,019,344–10,074,135, 58 genes, copy number 13: BOLA3P2, OR1M4P, OR1M1, OR7G2, OR7G1, OR7G15P, OR7G3, ZNF317, OR7D2, ELOCP29, OR7E16P, OR7E25P, OR7D4, OR7D1P, OR7E24, OR7E18P, OR7E19P, OR7H1P, ZNF699, AC011451.1, ZNF559, ZNF559-ZNF177, AC011451.2, ZNF177, AC011451.3, ZNF266, AC011451.4, ZNF560, AC008567.2, AC008567.3, AC008567.1, ZNF426, ZNF426-DT, ZNF121, ZNF561, ZNF561-AS1, ZNF562, RPS4XP22, ZNF812P, AC008759.3, AC008759.1, AC008759.2, ZNF846, AC008752.3, UBE2L4, AC008752.1, FBXL12, SNORA70, RPL10P15, UBL5, AC008752.2, PIN1, OLFM2, COL5A3, AC008742.1, RDH8, C3P1, MIR5589.
- chr19:27,638,483–38,426,305, 370 genes, copy number 9–14 (broad region; genes not listed).
- chr19:53,066,606–56,922,213, 320 genes, copy number 7–16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 693. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
